CPTAC case C3L-02951 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a60cf9e4-f150-4a9a-a9b7-4083431e4bb2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1956; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 61.6 years (22,502 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,797 days (4.9 years); Progression or recurrence: yes; Days to recurrence: 853 days (2.3 years); Days to last follow up: 1,797 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.8 cm (a second GDC size field records 7.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 11; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 720 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 1,051 days (2.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 853 days (2.3 years).
- Days to follow up: 1,051 days (2.9 years); Disease response: With Tumor.
- Days to follow up: 1,420 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,797 days (4.9 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 267.

Other clinical attributes
- Weight: 58.97 kg; Height: 154.94 cm; BMI: 24.56; DLCO (% of predicted): 65; FEV1/FVC after bronchodilator (%): 73; FEV1/FVC before bronchodilator (%): 68; FEV1 after bronchodilator (% of reference): 96; FEV1 before bronchodilator (% of reference): 54.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 20; Cigarettes per day: 10; Tobacco smoking onset year: 1977; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 45.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02951-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 341 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02951-22: Section location: Left Lower Lobe; Percent tumor nuclei: 70; Percent necrosis: 8.
- Sample C3L-02951-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 341 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02951-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
